Somatic mutation profile of tumor specimen TCGA-CZ-5454-01A (aliquot TCGA-CZ-5454-01A-01D-1501-10) from TCGA case TCGA-CZ-5454, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.2 years (23,083 days).
Specimen TCGA-CZ-5454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d6ab901-38f3-40c2-bac4-f08e7b598d4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5454-11A (Solid Tissue Normal), aliquot TCGA-CZ-5454-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a569231-860e-4111-80de-ead96e702b71

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Del 4, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD5 | c.2575G>T p.V859L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58977838; called by muse, mutect2, varscan2
- DDX42 | c.1714A>T p.N572Y | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63791057; called by muse, mutect2, varscan2
- GALNT7 | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV104369492, COSV53933861; called by muse, varscan2
- GPNMB | c.1406C>T p.T469I (on ENST00000381990 / NM_001005340.2; = p.T457I on NM_002510.3) | Missense Mutation (SNP) | VAF 102/175 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51700428; called by muse, mutect2, varscan2
- MEIOB | c.1255A>T p.I419F | Missense Mutation (SNP) | VAF 151/474 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV58055292; called by muse, mutect2, varscan2
- NLRP9 | c.1250G>T p.R417M | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs563256174, COSV60466733; called by muse, mutect2, varscan2
- PAPOLA | c.1289+1G>A p.X430_splice | Splice Site (SNP) | VAF 42/429 reads (10%) | catalogued as COSV53484338; called by muse, mutect2, varscan2
- PBRM1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 176/292 reads (60%) | catalogued as COSV56294959, COSV56298403; called by muse, mutect2, varscan2
- PSMD3 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761441485, COSV52859298; called by muse, mutect2, varscan2
- RIPK2 | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV55133387; called by muse, mutect2, varscan2
- SEC61B | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53060542, COSV99445518; called by muse, mutect2, varscan2
- STMN2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200432248, COSV55221709; called by muse, mutect2, varscan2
- TRAF3IP2 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV60676908; called by muse, mutect2, varscan2
- ZMYM6 | c.2047T>C p.S683P | Missense Mutation (SNP) | VAF 28/782 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100593264; called by muse, mutect2
- ARG1 | c.617dup p.G207Rfs*26 | Frame Shift Ins (INS) | VAF 116/355 reads (33%) | called by mutect2, pindel, varscan2
- CDK12 | c.3563del p.I1188Tfs*27 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- GTDC1 | c.406_407del p.S136Hfs*10 | Frame Shift Del (DEL) | VAF 59/172 reads (34%) | called by mutect2, pindel, varscan2
- OSCP1 | c.586_587del p.G196Sfs*15 (on ENST00000356637 / NM_001330493.1; = p.G186Sfs*15 on NM_145047.5) | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by pindel*, varscan2
- ZNF831 | c.3024del p.S1009Afs*56 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- GGT7 | c.1794G>A p.P598= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs375464567; called by muse, mutect2, varscan2
- LMLN | c.1422C>A p.S474= | Silent (SNP) | VAF 287/720 reads (40%) | catalogued as COSV57597698, COSV57604187; called by muse, mutect2, varscan2
- NR1I2 | c.255G>A p.E85= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1232349409, COSV61979419; called by muse, mutect2, varscan2
- RFC1 | c.2853G>A p.G951= (on ENST00000381897 / NM_001363496.2; = p.G950= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as rs760028696, COSV62899456; called by muse, mutect2, varscan2
- RPL3 | c.306C>T p.F102= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs1569161687, COSV53365444; called by muse, mutect2, varscan2
- SLC2A4RG | c.501T>A p.S167= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV55513537; called by muse, varscan2
- TTC37 | c.481A>C p.R161= | Silent (SNP) | VAF 238/670 reads (36%) | catalogued as COSV62456410; called by muse, mutect2
- YTHDF3 | c.750G>A p.P250= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs61745071; called by muse, mutect2, varscan2
